Gene-level copy-number profile of tumor specimen TCGA-HU-8244-01A from TCGA case TCGA-HU-8244, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 77.2 years (28,184 days).
Specimen TCGA-HU-8244-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.81b595ca-c3f1-47c8-8aec-823c5efe9ac6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-8244-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/92622658-0630-4681-a620-c14401c12ed0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 180; copy number 2: 51,214; copy number 3: 4,134; copy number 4: 4,290; copy number 6: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-8244-01A-11D-2338-01): tumor purity 0.9, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:15,280,764–15,280,873, 1 gene, copy number 6: RNA5SP475.

Autosomal genes at a single copy (total copy number 1): 180. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
